Gene-level copy-number profile of tumor specimen TCGA-AJ-A3EM-01A from TCGA case TCGA-AJ-A3EM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 70.0 years (25,557 days).
Specimen TCGA-AJ-A3EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.2b4f880f-6103-49a7-8c22-9fc3832c5241.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3EM-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b028800-1055-403d-a515-d3f1a5903ab2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 236; copy number 2: 16,893; copy number 3: 20,857; copy number 4: 15,995; copy number 5: 1,405; copy number 6: 3,639; copy number 7: 298; copy number 8: 39; copy number 9: 162; copy number 10: 78; copy number 11: 51; copy number 13: 38; copy number 15: 46; copy number 18: 35; copy number 19: 5; copy number 20: 20; copy number 22: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3EM-01A-11D-A20R-01): tumor purity 0.75, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,850,367, 1 gene: MIR4447.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 772 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,173,049–150,975,534, 42 genes, copy number 9–13 (within-gene range 3–13): AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1.
- chr1:153,661,788–154,548,147, 57 genes, copy number 10 (within-gene range 6–10): ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1, AL358472.5, DENND4B, CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13, RPS27, NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698, TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10.
- chr1:167,052,836–168,729,206, 42 genes, copy number 7 (within-gene range 6–7): GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT.
- chr1:172,138,397–172,468,831, 8 genes, copy number 7: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105.
- chr1:211,258,377–211,853,703, 20 genes, copy number 20 (within-gene range 6–20): RCOR3, TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1.
- chr1:219,557,192–220,148,041, 11 genes, copy number 7: AL356364.1, ZC3H11B, SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12.
- chr1:232,983,435–233,543,633, 6 genes, copy number 7 (within-gene range 6–7): PCNX2, RPS7P3, AL133380.1, MAP3K21, RNU4-77P, AL360006.1.
- chr1:234,212,606–234,980,804, 32 genes, copy number 11: AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr1:244,653,103–245,709,432, 19 genes, copy number 11 (within-gene range 5–11): DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8.
- chr2:113,157,325–113,563,298, 12 genes, copy number 7 (within-gene range 3–7): PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4.
- chr3:107,834,586–107,928,907, 2 genes, copy number 8 (within-gene range 3–8): LINC00636, LINC00635.
- chr3:138,608,606–139,006,268, 11 genes, copy number 18: FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A.
- chr3:139,019,031–139,125,171, 4 genes, copy number 18: PRR23B, PRR23C, RPL7L1P7, BPESC1.
- chr3:149,030,127–151,437,072, 66 genes, copy number 15–18 (within-gene range 3–18) (broad region; genes not listed).
- chr3:187,668,912–195,543,386, 121 genes, copy number 9–22 (within-gene range 6–22) (broad region; genes not listed).
- chr6:42,564,029–42,746,103, 5 genes, copy number 9 (within-gene range 3–9): UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC.
- chr6:111,555,381–111,606,906, 2 genes, copy number 7 (within-gene range 4–7): TRAF3IP2, Z97989.1.
- chr6:162,727,132–165,117,524, 26 genes, copy number 7 (within-gene range 4–7): PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1, AL136100.1.
- chr8:18,104,797–18,401,218, 8 genes, copy number 9: AC124242.3, NAT1, MTND4LP26, NATP, AC025062.1, AC025062.3, AC025062.2, NAT2.
- chr8:101,128,987–101,492,499, 18 genes, copy number 10: AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr8:127,253,213–129,683,770, 29 genes, copy number 9–19 (within-gene range 6–19): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:143,157,914–143,656,418, 31 genes, copy number 8: LY6H, GPIHBP1, ZFP41, AC138696.1, GLI4, MINCR, ZNF696, AC138696.2, TOP1MT, RNU6-220P, RHPN1-AS1, RHPN1, AC105118.1, MAFA-AS1, MAFA, ZC3H3, AC067930.9, AC067930.3, RN7SKP175, GSDMD, MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1, EEF1D, TIGD5, PYCR3, GFUS, AC067930.2, ZNF623.
- chr9:33,041,765–33,662,663, 29 genes, copy number 7 (within-gene range 4–7): SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2.
- chr10:11,453,946–11,764,070, 4 genes, copy number 9 (within-gene range 4–9): USP6NL, AL512631.2, AL512631.1, ECHDC3.
- chr10:24,157,835–24,275,781, 3 genes, copy number 7: NUP35P1, AC063961.1, MIR603.
- chr10:118,572,871–118,595,648, 2 genes, copy number 8: SLC25A18P1, PRLHR.
- chr11:65,260,996–65,862,026, 49 genes, copy number 7 (within-gene range 3–7): AP000944.6, POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489, RELA, RELA-DT, RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1, CFL1.
- chr12:71,938,845–72,186,618, 2 genes, copy number 7: TPH2, AC090109.1.
- chr14:32,329,298–32,882,830, 5 genes, copy number 7 (within-gene range 4–7): AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.
- chr15:80,554,609–80,581,239, 3 genes, copy number 7: AC108451.1, AC108451.2, MIR5572.
- chr17:4,364,164–4,488,208, 2 genes, copy number 10 (within-gene range 4–10): RN7SL774P, SPNS3.
- chr17:43,412,427–43,706,709, 11 genes, copy number 7: RNU6-470P, MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1, DHX8, ETV4, Metazoa_SRP, MEOX1, LINC02594.
- chr17:75,588,058–75,825,799, 13 genes, copy number 7: MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1.
- chr18:3,190,397–3,459,978, 12 genes, copy number 7 (within-gene range 4–7): AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1.
- chr18:61,592,375–61,758,464, 3 genes, copy number 7 (within-gene range 4–7): AC105094.2, AC105094.1, LINC01544.
- chr20:10,172,522–10,307,418, 3 genes, copy number 7 (within-gene range 4–7): AL354824.1, AL354824.2, SNAP25.
- chr20:32,109,714–32,439,319, 11 genes, copy number 7 (within-gene range 4–7): TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.
- chr20:51,098,138–51,768,390, 6 genes, copy number 7 (within-gene range 5–7): AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1.
- chr20:52,858,338–52,890,386, 2 genes, copy number 8: AL121902.1, RPL36P1.
- chr20:62,183,029–62,685,785, 31 genes, copy number 7 (within-gene range 4–7): MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1.

Autosomal genes at a single copy (total copy number 1): 236. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
